Somatic mutation profile of tumor specimen TCGA-L5-A88V-01A (aliquot TCGA-L5-A88V-01A-11D-A351-09) from TCGA case TCGA-L5-A88V, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 60.4 years (22,066 days).
Specimen TCGA-L5-A88V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5269b4d-375d-42e3-bcd5-4ab5874f8c1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A88V-11A (Solid Tissue Normal), aliquot TCGA-L5-A88V-11A-11D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bbfce01-4d28-462a-9a19-1c05cbee1d74

The open-access MAF lists 172 somatic variants for this specimen: 131 protein-altering or splice-affecting, 38 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, Silent 38, Nonsense Mutation 14, In Frame Del 2, 3'UTR 2, Frame Shift Ins 2, Splice Site 2, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 15/26 reads (58%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 28/41 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACHE | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV53822791; called by muse, mutect2, varscan2
- ACTRT2 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs138316843; called by muse, mutect2, varscan2
- ANKRD50 | c.1667G>A p.G556D | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs769326497; called by muse, mutect2, varscan2
- C8orf74 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs778382431; called by muse, mutect2, varscan2
- CA10 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV99565727; called by muse, mutect2, varscan2
- CACNA1E | c.4744C>T p.R1582C | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1365641463, COSV62396540; called by muse, varscan2
- CACNA1E | c.4762C>T p.R1588C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100701337; called by muse, varscan2
- CCNB2 | c.698T>C p.F233S | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778475417; called by muse, mutect2, varscan2
- CDH2 | c.1598+1G>T p.X533_splice | Splice Site (SNP) | VAF 12/36 reads (33%) | catalogued as COSV52271049, COSV52298431; called by muse, varscan2
- CHST3 | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs751134642; called by muse, varscan2
- CSNK1E | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as rs1200940381; called by muse, mutect2, varscan2
- DLG1 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as rs763415685; called by muse, mutect2, varscan2
- DNAH10 | c.5677G>A p.G1893S (on ENST00000409039; = p.G1832S on NM_207437.3) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768459284, COSV68987919; called by muse, mutect2, varscan2
- EFCC1 | c.1336G>A p.G446S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0.031); catalogued as rs567338824, COSV71401788; called by muse, mutect2, varscan2
- EID3 | c.326C>A p.S109* | Nonsense Mutation (SNP) | VAF 34/44 reads (77%) | catalogued as COSV100723526; called by muse, mutect2, varscan2
- ELOVL5 | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as rs756040737; called by muse, mutect2, varscan2
- FLYWCH1 | c.353G>A p.R118K (on ENST00000253928 / NM_001308068.2; = p.R117K on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1294366098; called by muse, mutect2, varscan2
- GRM4 | c.2089G>A p.A697T | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.081); catalogued as rs374098086, COSV100947003; called by muse, mutect2, varscan2
- H4C12 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as COSV100694732, COSV100694790, COSV100694810; called by muse, mutect2, varscan2
- HAS1 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs777326196; called by muse, mutect2, varscan2
- HDAC9 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 82/176 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs1190611465; called by muse, mutect2, varscan2
- HOXD4 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV100106913, COSV60459563; called by muse, mutect2
- HS3ST5 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.706); catalogued as rs374141405; called by muse, mutect2, varscan2
- IGSF11 | c.976C>A p.P326T (on ENST00000393775 / NM_001015887.3; = p.P325T on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV61165817; called by muse, mutect2, varscan2
- INHBB | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs770722399, COSV99736264; called by muse, mutect2, varscan2
- INPPL1 | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53354991; called by muse, mutect2, varscan2
- JARID2 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as rs746559577; called by muse, mutect2, varscan2
- KIF16B | c.2569G>A p.E857K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.254); catalogued as COSV100734601; called by muse, mutect2, varscan2
- LAMA1 | c.7639G>A p.V2547I | Missense Mutation (SNP) | VAF 55/78 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs367598361; called by muse, mutect2, varscan2
- LRP12 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 84/150 reads (56%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as rs1407231110; called by muse, mutect2, varscan2
- LSP1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs147990493; called by muse, mutect2, varscan2
- LY75 | c.1735C>T p.R579W | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs545499741; called by muse, mutect2, varscan2
- MAP1B | c.5860G>A p.G1954R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as rs776597827; called by muse, mutect2, varscan2
- MVP | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as rs1030443313; called by muse, mutect2, varscan2
- N4BP2L2 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs202129118, COSV57229578; called by muse, mutect2, varscan2
- NAT8L | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs775990289, COSV59051094; called by muse, mutect2, varscan2
- NEB | c.11341C>T p.Q3781* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99428613; called by muse, mutect2, varscan2
- NFKBIA | c.927_928del p.F310Wfs*30 | Frame Shift Del (DEL) | VAF 42/93 reads (45%) | catalogued as rs1229730339; called by pindel, varscan2
- NUP153 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 12/96 reads (13%) | catalogued as COSV50449538; called by muse, mutect2, varscan2
- OR4P4 | c.448G>T p.G150* | Nonsense Mutation (SNP) | VAF 31/33 reads (94%) | catalogued as COSV58921068; called by muse, mutect2, varscan2
- OR5L2 | c.441C>A p.C147* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV65725338; called by muse, mutect2, varscan2
- PLPP6 | c.469A>G p.S157G | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as rs1401921736; called by muse, mutect2
- PLXNA4 | c.5407G>A p.D1803N | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58138356; called by muse, mutect2, varscan2
- PTPRN2 | c.1597G>A p.V533I | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.547); catalogued as rs753171784, COSV67023155; called by muse, mutect2, varscan2
- PTPRZ1 | c.4930G>A p.V1644M | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774136227, COSV66445202; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2081C>T p.S694F | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV51489495; called by muse, mutect2, varscan2
- RCAN3 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV100980322; called by muse, mutect2, varscan2
- RPL23 | c.98G>C p.G33A | Missense Mutation (SNP) | VAF 693/783 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55559667; called by muse, mutect2, varscan2
- RYR2 | c.12120G>C p.K4040N | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.87); catalogued as COSV63668568; called by muse, mutect2
- SALL1 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs756599740, COSV51764349, COSV99179263; called by muse, mutect2, varscan2
- SALL1 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV51752910, COSV51760752; called by muse, mutect2, varscan2
- SCN8A | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs752265946, COSV61994238; called by muse, mutect2, varscan2
- SKAP2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1025140851, COSV61725796; called by muse, mutect2, varscan2
- SON | c.5528C>A p.S1843Y | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV51668196; called by muse, mutect2, varscan2
- SYMPK | c.2098C>T p.R700* | Nonsense Mutation (SNP) | VAF 23/75 reads (31%) | catalogued as COSV99841469; called by muse, mutect2, varscan2
- TFAP4 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV104390905, COSV52598747; called by muse, mutect2, varscan2
- TOE1 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1433886134; called by muse, mutect2, varscan2
- TSPOAP1 | c.1459G>A p.V487M | Missense Mutation (SNP) | VAF 56/95 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs758177348; called by muse, mutect2, varscan2
- UFSP2 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs752742695, COSV52992067; called by muse, mutect2, varscan2
- USH2A | c.5266G>A p.V1756I | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs143208990; called by muse, mutect2, varscan2
- USP12 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.74); catalogued as COSV56656110; called by muse, mutect2, varscan2
- VCPIP1 | c.3595G>A p.V1199M | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.558); catalogued as rs189491128; called by muse, mutect2, varscan2
- WRAP73 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as rs143137458; called by muse, mutect2, varscan2
- ZNF672 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs371348856, COSV60637620; called by muse, varscan2
- ADAM12 | c.1975G>T p.E659* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- AMY2B | c.575C>G p.S192C | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- ANKRD17 | c.4466G>T p.R1489M | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- ARID4B | c.433_435del p.R145del | In Frame Del (DEL) | VAF 27/92 reads (29%) | called by pindel, varscan2
- BICC1 | c.2534-1G>A p.X845_splice | Splice Site (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- C6 | c.2081A>T p.Q694L | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- CAMK1D | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPZA1 | c.813G>A p.W271* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- CDH2 | c.1511T>A p.I504N | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, varscan2
- CSMD1 | c.8053G>C p.D2685H (on ENST00000520002; = p.D2684H on NM_033225.6) | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2
- CXCR3 | c.167T>G p.L56R | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, mutect2
- DGKK | c.765C>A p.H255Q | Missense Mutation (SNP) | VAF 52/65 reads (80%) | SIFT tolerated (0.19); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- DMBT1 | c.6104C>A p.T2035N (on ENST00000338354 / NM_001377530.1; = p.T1278N on NM_004406.3) | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- ERBB2 | c.1985T>A p.L662Q | Missense Mutation (SNP) | VAF 568/2255 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- FAM83B | c.2773C>T p.R925* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- FBXO15 | c.1467_1503delinsATTGTCAACCTGGTCCTTT p.I490_K501delinsLSTWSF | In Frame Del (DEL) | VAF 20/50 reads (40%) | called by pindel, varscan2*
- FBXO15 | c.1132_1133del p.K378Efs*5 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | called by mutect2, pindel, varscan2
- FGF1 | c.334T>C p.Y112H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FGF7 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 170/443 reads (38%) | called by muse, varscan2
- FNIP1 | c.1102A>C p.S368R | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- GTF3C3 | c.1238T>G p.V413G | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- HIP1 | c.1981G>A p.V661I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- HIVEP1 | c.6057G>A p.W2019* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- HMX3 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- IGKV1-12 | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- JAK3 | c.2885A>T p.H962L | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- JPH1 | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by mutect2, varscan2
- KCNK1 | c.509T>A p.I170N | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KIAA0319 | c.3197G>T p.S1066I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- LIG4 | c.2262T>A p.F754L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- LMTK2 | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- LRRC39 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MICAL2 | c.140G>T p.R47I | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- NAPB | c.163G>C p.A55P | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- NES | c.4209_4222del p.W1403* | Nonsense Mutation (DEL) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- NEUROD4 | c.787T>G p.F263V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- NHLRC3 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NKRF | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- NME8 | c.254T>A p.V85D | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- NUP188 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2
- OR4K14 | c.92dup p.F32Lfs*11 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by pindel, varscan2
- OTOF | c.2912G>T p.S971I (on ENST00000272371 / NM_194248.3; = p.S224I on NM_004802.4) | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PCGF2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PCGF2 | c.609G>T p.K203N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PI4KA | c.1477T>A p.C493S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PLCH1 | c.5002T>A p.F1668I (on ENST00000340059 / NM_001130960.2; = p.F1660I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLEKHA6 | c.3053C>A p.P1018H | Missense Mutation (SNP) | VAF 76/130 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PNISR | c.1776A>C p.R592S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PRAMEF2 | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.98); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- PSME2 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.93); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- RYR3 | c.4673A>C p.H1558P | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SHKBP1 | c.1804C>A p.L602M | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SLC12A5 | c.2548G>A p.D850N (on ENST00000454036 / NM_001134771.2; = p.D827N on NM_020708.5) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SLC1A6 | c.1544G>C p.G515A | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- SLC47A1 | c.362T>C p.L121P | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SRL | c.601C>A p.Q201K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TPSG1 | c.325C>A p.Q109K | Missense Mutation (SNP) | VAF 69/105 reads (66%) | SIFT tolerated (0.15); PolyPhen benign (0.041); called by muse, mutect2
- TTN | c.71057G>A p.R23686K (on ENST00000591111; = p.R16262K on NM_003319.4) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | PolyPhen benign (0.343); called by muse, mutect2, varscan2
- VDAC1 | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VPS13D | c.5791G>C p.E1931Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- WDFY1 | c.981C>G p.S327R | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- ZMAT4 | c.624C>A p.N208K | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF281 | c.860G>T p.R287I | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF417 | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2
- ZNF562 | c.1223C>G p.T408S (on ENST00000453372 / NM_001130032.2; = p.T336S on NM_017656.4) | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- ACADSB | c.1101G>A p.A367= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs145295182; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADGRB3 | c.2938A>C p.R980= | Silent (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- AUTS2 | c.1644C>T p.H548= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs779465333, COSV61418055; called by muse, mutect2, varscan2
- AXL | c.1695T>C p.A565= (on ENST00000301178 / NM_021913.5; = p.A556= on NM_001699.6) | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV56563748; called by muse, mutect2, varscan2
- BAHCC1 | c.3102C>T p.S1034= | Silent (SNP) | VAF 46/91 reads (51%) | catalogued as rs868984769; called by muse, mutect2, varscan2
- CHIC1 | c.465A>G p.T155= | Silent (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- COL20A1 | c.45G>A p.L15= | Silent (SNP) | VAF 34/168 reads (20%) | called by muse, mutect2, varscan2
- COL25A1 | c.69C>T p.A23= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs757371355; called by muse, mutect2, varscan2
- COQ8A | c.543C>T p.A181= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs774889574; called by muse, mutect2, varscan2
- EBF1 | c.1521C>T p.N507= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs763968946, COSV58184625; called by muse, mutect2, varscan2
- ENOX1 | c.1098G>A p.S366= | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as rs770349357, COSV54895942; called by muse, mutect2, varscan2
- EPB41L3 | c.312C>A p.V104= | Silent (SNP) | VAF 15/88 reads (17%) | called by muse, mutect2, varscan2
- F3 | c.162T>A p.I54= | Silent (SNP) | VAF 29/80 reads (36%) | called by muse, mutect2, varscan2
- FBXL2 | c.243G>A p.R81= | Silent (SNP) | VAF 42/84 reads (50%) | called by muse, mutect2, varscan2
- FGF23 | c.741C>T p.F247= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV52976035, COSV99426566; called by muse, mutect2
- GALNT9 | c.1764G>A p.S588= (on ENST00000328957 / NM_001122636.2; = p.S222= on NM_021808.3) | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs763335985; called by muse, mutect2, varscan2
- GGN | c.501C>T p.P167= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- GIMAP4 | c.411C>A p.I137= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV55432515; called by muse, mutect2, varscan2
- GRIFIN | c.204G>A p.P68= | Silent (SNP) | VAF 116/243 reads (48%) | catalogued as rs746439979; called by muse, mutect2, varscan2
- IRX1 | c.687C>T p.D229= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs758614856; called by muse, mutect2, varscan2
- LARP7 | c.1563C>T p.L521= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs375007095; called by muse, mutect2, varscan2
- LCE2D | c.267C>T p.P89= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as rs764207827; called by muse, mutect2, varscan2
- LRCH4 | c.252C>G p.P84= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs200187564, COSV53827147; called by muse, mutect2, varscan2
- NUDT8 | c.507C>T p.P169= | Silent (SNP) | VAF 372/411 reads (91%) | catalogued as rs763761783, COSV56875580; called by muse, mutect2, varscan2
- PCOLCE2 | c.558A>T p.V186= | Silent (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- PHTF1 | c.465A>G p.G155= | Silent (SNP) | VAF 20/27 reads (74%) | catalogued as rs150320233; called by muse, mutect2, varscan2
- PRIMA1 | c.450C>T p.N150= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs756623642, COSV60263603; called by muse, mutect2
- PSG1 | c.549T>C p.N183= | Silent (SNP) | VAF 59/203 reads (29%) | catalogued as rs1353420575; called by muse, mutect2, varscan2
- REEP3 | c.399T>A p.A133= | Silent (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2
- RNF19B | c.1077G>A p.V359= | Silent (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- RP1 | c.6084G>A p.L2028= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV55127354; called by muse, mutect2, varscan2
- SAV1 | c.933C>T p.Y311= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs762207330; called by muse, mutect2, varscan2
- SLC10A7 | c.63T>C p.A21= | Silent (SNP) | VAF 35/56 reads (63%) | called by muse, mutect2, varscan2
- SNX18 | c.984G>A p.P328= | Silent (SNP) | VAF 30/40 reads (75%) | catalogued as rs751209267, COSV57988882, COSV57989078; called by muse, mutect2, varscan2
- TNKS1BP1 | c.5178G>A p.K1726= | Silent (SNP) | VAF 14/16 reads (88%) | called by muse, mutect2, varscan2
- TSC22D4 | c.936C>T p.S312= | Silent (SNP) | VAF 43/91 reads (47%) | catalogued as rs756249806; called by muse, mutect2, varscan2
- TSPAN2 | c.225C>T p.F75= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as rs759821939; called by muse, mutect2, varscan2
- ZC3H13 | c.1404G>A p.R468= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV54463783; called by muse, mutect2, varscan2
- LARS2 | c.*971C>G | 3'UTR (SNP) | VAF 28/49 reads (57%) | called by muse, mutect2, varscan2
- LINC02877 | n.381C>A | RNA (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- WHRN | c.*1A>T | 3'UTR (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
